Gene-level copy-number profile of tumor specimen TCGA-CC-A7IJ-01A from TCGA case TCGA-CC-A7IJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 56.8 years (20,751 days).
Specimen TCGA-CC-A7IJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c3f2b829-11d4-4c3b-8dac-0d6084b016a8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A7IJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9229e7d-0fd3-4d33-83f2-5b0e3bfeac8f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 762; copy number 2: 29,094; copy number 3: 21,177; copy number 4: 7,144; copy number 5: 1,076; copy number 6: 206; copy number 7: 89; copy number 8: 5; copy number 9: 23; copy number 10: 1; copy number 12: 47; copy number 22: 59; copy number 26: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A7IJ-01A-11D-A33P-01): tumor purity 0.51, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,167,357, 1 gene: RNU6-904P.
- chr11:81,821,272–82,718,299, 1 gene (within-gene range 0–2): MIR4300HG.
- chr11:83,455,012–85,627,922, 1 gene (within-gene range 0–2): DLG2.
- chr11:84,545,131–87,330,052, 54 genes: HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1.
- chr16:11,555–287,215, 30 genes: DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25, RHBDF1, Z69720.2, MPG, NPRL3, Z69720.1, Z69666.1, HBZ, HBM, HBZP1, HBAP1, HBA2, HBA1, Y_RNA, HBQ1, Z69706.1, LUC7L, Z69890.1, FAM234A, RGS11, Z69667.1, ARHGDIG, PDIA2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,552 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–18,955,049, 293 genes, copy number 5 (broad region; genes not listed).
- chr3:85,992,183–88,168,729, 26 genes, copy number 7: CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38.
- chr3:168,858,659–175,810,548, 99 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:176,415,439–180,037,053, 58 genes, copy number 5 (within-gene range 2–5): LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13, USP13, PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2, AC092939.1.
- chr3:180,413,008–196,243,178, 341 genes, copy number 5–6 (broad region; genes not listed).
- chr4:48,341,529–49,062,081, 12 genes, copy number 5–7: SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr6:60,281,444–63,779,336, 30 genes, copy number 5 (within-gene range 3–5): AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–64,631,682, 5 genes, copy number 5–10: AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2.
- chr6:69,866,556–70,212,468, 2 genes, copy number 7: COL19A1, RPL37P15.
- chr9:14,475–10,612,723, 141 genes, copy number 6–26 (within-gene range 4–26) (broad region; genes not listed).
- chr9:9,442,060–15,307,360, 55 genes, copy number 6–9 (within-gene range 2–9): RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B.
- chr10:4,024,903–7,154,236, 79 genes, copy number 5 (broad region; genes not listed).
- chr10:43,077,064–43,267,065, 4 genes, copy number 5: RET, AC010864.1, CSGALNACT2, RASGEF1A.
- chr10:53,038,285–53,766,614, 4 genes, copy number 5: SNRPEP8, AC036101.1, RNA5SP318, AL365496.1.
- chr10:56,357,227–56,364,714, 2 genes, copy number 6: ZWINT, AC010996.1.
- chr10:73,007,217–78,697,022, 137 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr10:83,067,962–83,314,475, 2 genes, copy number 5: RNU6-478P, MARK2P15.
- chr10:85,599,552–86,366,795, 1 gene, copy number 5 (within-gene range 3–5): GRID1.
- chr10:86,052,448–86,969,481, 17 genes, copy number 5 (within-gene range 3–5): RNA5SP322, MIR346, AL844892.2, AL844892.1, WAPL, RNU6-780P, AL731569.1, RPL7AP8, OPN4, LDB3, AC067750.1, BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG.
- chr10:88,664,441–90,225,443, 45 genes, copy number 5 (within-gene range 3–5): LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1, PANK1, MIR107, AL157400.5, AL157400.2, AL157400.1, AL157400.3, AL157400.4, KIF20B, MTND5P42, LINC00865, MARK2P16, LINC01374, LINC01375, SNRPD2P1, AL139340.1.
- chr10:90,871,952–91,667,782, 16 genes, copy number 5: RPP30, Y_RNA, ANKRD1, RNU6-740P, AL365434.1, AL365434.2, LINC00502, DDX18P6, NUDT9P1, AL731553.1, PCGF5, HECTD2, AL161798.1, RPS27P1, PPP1R3C, GAPDHP28.
- chr10:125,574,371–126,798,708, 27 genes, copy number 5: TEX36-AS1, TEX36, ALDOAP2, AL158835.1, EDRF1-DT, AL158835.3, AL158835.2, EDRF1, EDRF1-AS1, MMP21, UROS, MIR4484, BCCIP, DHX32, Metazoa_SRP, RNU2-42P, FANK1, GNG10P1, FANK1-AS1, ADAM12, RNA5SP328, SAR1AP2, AL589787.2, LINC00601, C10orf90, AL589787.1, AL512272.1.
- chr10:126,988,095–127,026,507, 2 genes, copy number 5: AL359094.1, AL359094.2.
- chr10:127,549,309–128,085,855, 9 genes, copy number 5 (within-gene range 3–5): NPS, AL391005.1, FOXI2, BUB1P1, CLRN3, PTPRE, AL158166.2, AL158166.1, AL390236.1.
- chr10:131,772,398–132,976,354, 26 genes, copy number 5: LINC01164, AL450307.1, AL607033.1, FP565171.1, PPP2R2D, BNIP3, AL162274.2, AL162274.1, AL162274.3, JAKMIP3, AL512622.1, DPYSL4, STK32C, LRRC27, PWWP2B, AL451069.2, AL451069.3, LINC02870, AL451069.1, LINC01165, INPP5A, NKX6-2, CFAP46, LINC01166, LINC01167, LINC01168.
- chr10:133,083,073–133,088,491, 1 gene, copy number 5: ADGRA1-AS1.
- chr11:67,398,181–70,436,584, 115 genes, copy number 5–12 (within-gene range 2–12) (broad region; genes not listed).
- chr11:70,477,277–70,477,592, 1 gene, copy number 12: AP001271.1.
- chr12:72,610,678–72,728,844, 2 genes, copy number 6: CHCHD3P2, AC133480.1.

Autosomal genes at a single copy (total copy number 1): 169. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
